Somatic mutation profile of tumor specimen TCGA-5P-A9KH-01A (aliquot TCGA-5P-A9KH-01A-11D-A42J-10) from TCGA case TCGA-5P-A9KH, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 77.2 years (28,193 days).
Specimen TCGA-5P-A9KH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e3673d5-f24a-4521-abd9-919d5d4e3fa6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9KH-10A (Blood Derived Normal), aliquot TCGA-5P-A9KH-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1383735d-24c6-4932-8a04-2b7d16f69798

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 2, Translation Start Site 1, In Frame Ins 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.764_766del p.I255del | In Frame Del (DEL) | VAF 17/65 reads (26%) | hotspot (GDC flag); catalogued as rs1064794309; called by pindel, varscan2
- ABHD18 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV101180745; called by muse, mutect2, varscan2
- DHCR24 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.047); catalogued as rs1010206690, COSV64875028; called by muse, mutect2
- DUOXA1 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs374411208; called by muse, mutect2, varscan2
- EPHB4 | c.1978G>T p.E660* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | catalogued as COSV100639504; called by muse, mutect2, varscan2
- FASTKD2 | c.156A>T p.K52N | Missense Mutation (SNP) | VAF 11/330 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV99378992; called by muse, mutect2
- GABRB2 | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.269); catalogued as COSV50904358; called by muse, mutect2, varscan2
- GPR137C | c.1152G>T p.M384I | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100397603; called by muse, mutect2, varscan2
- GRM3 | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV100861983; called by muse, mutect2
- KMT2D | c.5149C>A p.Q1717K | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as COSV99981892; called by muse, mutect2, varscan2
- LMTK3 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.033); catalogued as COSV99540501; called by muse, mutect2
- MEGF8 | c.6055A>G p.T2019A (on ENST00000251268 / NM_001271938.2; = p.T1952A on NM_001410.3) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as COSV99236359; called by muse, mutect2, varscan2
- MYOM2 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100037497, COSV50771165; called by muse, mutect2, varscan2
- SEL1L3 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 38/86 reads (44%) | catalogued as rs747819559, COSV53538227; called by muse, mutect2, varscan2
- SLC4A2 | c.2607G>A p.M869I | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs896065827, COSV99879759; called by muse, mutect2, varscan2
- SPINK5 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 96/449 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as COSV99806723; called by muse, mutect2, varscan2
- TAC4 | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100402771; called by muse, mutect2, varscan2
- TRIM22 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs199987600, COSV66091660; called by muse, mutect2, varscan2
- GLG1 | c.2994C>A p.D998E | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MCTP2 | c.2360+1_2360+3del p.X787_splice | Splice Site (DEL) | VAF 30/120 reads (25%) | called by mutect2, pindel, varscan2
- UBXN2B | c.270_272dup p.E91dup | In Frame Ins (INS) | VAF 47/414 reads (11%) | called by mutect2, pindel, varscan2
- CCDC74A | c.597C>T p.D199= | Silent (SNP) | VAF 40/64 reads (63%) | catalogued as rs766326624, COSV99723726; called by muse, mutect2, varscan2
- HMCN1 | c.14535G>T p.V4845= | Silent (SNP) | VAF 61/85 reads (72%) | catalogued as COSV99629472; called by muse, mutect2, varscan2
- PRUNE2 | c.246C>T p.S82= | Silent (SNP) | VAF 74/191 reads (39%) | catalogued as rs759035052, COSV100943023; called by muse, mutect2, varscan2
- SLC13A5 | c.1335G>A p.P445= | Silent (SNP) | VAF 35/43 reads (81%) | catalogued as rs138802643; called by muse, mutect2, varscan2
